Somatic mutation profile of tumor specimen TCGA-P4-AAVL-01A (aliquot TCGA-P4-AAVL-01A-11D-A42J-10) from TCGA case TCGA-P4-AAVL, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 85.1 years (31,082 days).
Specimen TCGA-P4-AAVL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f187f845-1c45-4bb3-aaa4-9e84aebf3f60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-AAVL-11A (Solid Tissue Normal), aliquot TCGA-P4-AAVL-11A-11D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7c30c66-dc8e-442c-a45c-d1fb1238771e

The open-access MAF lists 84 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Frame Shift Del 6, Frame Shift Ins 4, Splice Site 2, Nonsense Mutation 2, RNA 1, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUBN | c.2496dup p.P833Sfs*2 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs1554816715; ClinVar: pathogenic; called by mutect2, varscan2
- ABCC12 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as rs747210056, COSV100253055; called by muse, mutect2, varscan2
- ABCD3 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100239033; called by muse, mutect2, varscan2
- ACAP3 | c.430A>G p.R144G | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100686653; called by muse, mutect2, varscan2
- ADGRA2 | c.1855A>G p.I619V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs377757244; called by muse, mutect2, varscan2
- ANKS1B | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 129/196 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100247203; called by muse, mutect2, varscan2
- C16orf72 | c.299T>A p.L100H | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100589105; called by muse, mutect2, varscan2
- CDH23 | c.8310C>G p.A2770= | Splice Region (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99823014; called by muse, mutect2, varscan2
- CDK8 | c.1180A>T p.S394C | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV101037474; called by muse, mutect2, varscan2
- CHST5 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs769347573, COSV60341133; called by muse, mutect2, varscan2
- CSDE1 | c.323T>A p.V108D | Missense Mutation (SNP) | VAF 132/316 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99795692; called by muse, mutect2, varscan2
- DHX8 | c.2900T>A p.L967Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99292513; called by muse, mutect2, varscan2
- DPEP1 | c.1219T>C p.C407R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99878661; called by muse, mutect2, varscan2
- DUT | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); catalogued as COSV100485308; called by muse, mutect2
- FNIP2 | c.3095C>G p.S1032C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV100033142; called by muse, mutect2, varscan2
- FZR1 | c.503C>G p.T168S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100553780; called by muse, mutect2, varscan2
- GABRQ | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 79/95 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782699208, COSV64782303; called by muse, mutect2, varscan2
- GIMAP1 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as rs1448707179, COSV56190124; called by muse, mutect2, varscan2
- GJB3 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as rs201314683, COSV64904769; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- IFT122 | c.700G>A p.E234K (on ENST00000348417 / NM_052989.3; = p.E285K on NM_052985.4) | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56199588; called by muse, mutect2, varscan2
- JMJD1C | c.5572T>C p.W1858R | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550748; called by muse, mutect2, varscan2
- KALRN | c.4583C>T p.T1528I | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99566520; called by muse, mutect2, varscan2
- LRRK1 | c.4858G>T p.A1620S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV99442199; called by muse, mutect2, varscan2
- LRTM1 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV99836162; called by muse, mutect2, varscan2
- MAGIX | c.988G>A p.G330R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100891916; called by muse, mutect2, varscan2
- MKKS | c.436A>C p.S146R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV100726309; called by muse, mutect2, varscan2
- MUTYH | c.1063T>C p.F355L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs587781601, COSV100588125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH10 | c.1387T>C p.F463L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99346006; called by muse, mutect2, varscan2
- MYH2 | c.1516A>T p.K506* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | catalogued as COSV99820697; called by muse, mutect2, varscan2
- MYO7B | c.5300G>C p.C1767S | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV101268342; called by muse, mutect2, varscan2
- NBPF11 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1187509012, COSV100982129; called by muse, mutect2, varscan2
- NOL6 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.087); catalogued as rs546933819, COSV99955045; called by muse, mutect2, varscan2
- NUP160 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.462); catalogued as rs1205827289, COSV101021592; called by muse, mutect2
- OPTN | c.1166T>A p.L389Q | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99537707; called by muse, mutect2, varscan2
- PCDHB3 | c.1846G>C p.G616R | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs782736232, COSV50606885, COSV99166133; called by muse, mutect2, varscan2
- PLIN4 | c.1525A>C p.T509P (on ENST00000301286; = p.T524P on NM_001367868.2) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100013877; called by muse, mutect2, varscan2
- PLXNA4 | c.3809C>T p.T1270M | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444586597, COSV100326223; called by muse, mutect2, varscan2
- PLXNB2 | c.2969C>T p.P990L | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63781140, COSV63783501; called by muse, mutect2, varscan2
- POLE | c.4609C>T p.L1537F | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.158); catalogued as rs1418237375, COSV100267792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP7 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 76/216 reads (35%) | catalogued as COSV100292187; called by muse, mutect2, varscan2
- PRKACG | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99599492; called by muse, mutect2, varscan2
- RAPGEF6 | c.2918C>G p.P973R | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99727415; called by muse, mutect2, varscan2
- RASGRF2 | c.3334T>C p.W1112R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99429950; called by muse, mutect2, varscan2
- RELN | c.403C>G p.H135D | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100634501; called by muse, mutect2, varscan2
- SACS | c.7274G>A p.R2425Q | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as rs771583552, CM1515367, COSV101207610; called by muse, mutect2, varscan2
- SCARF1 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV53961078, COSV99556847; called by muse, mutect2, varscan2
- SEL1L3 | c.3100A>T p.N1034Y | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV99340962; called by muse, mutect2, varscan2
- SLC4A8 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV100177324, COSV60654142; called by muse, mutect2, varscan2
- SND1 | c.2237A>G p.Y746C | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100690899; called by muse, mutect2, varscan2
- TMPRSS11F | c.630G>T p.R210S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100678716; called by muse, mutect2, varscan2
- TNPO2 | c.1949A>G p.E650G | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV100790396; called by muse, mutect2, varscan2
- ZBTB3 | c.854T>A p.V285D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs746083425, COSV101188999; called by muse, mutect2, varscan2
- ZNF425 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.086); catalogued as rs764655232, COSV65200647; called by muse, mutect2, varscan2
- ZNF536 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs747462173, COSV100835934, COSV62817581; called by muse, mutect2, varscan2
- ARHGEF40 | c.1467del p.G490Afs*37 | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | called by pindel, varscan2
- CALCR | c.570-8_570-1delinsA p.X190_splice (on ENST00000649521 / NM_001164737.2; = p.X174_splice on NM_001742.4) | Splice Site (DEL) | VAF 27/159 reads (17%) | called by pindel, varscan2*
- CHP1 | c.293dup p.S99Efs*25 | Frame Shift Ins (INS) | VAF 74/241 reads (31%) | called by mutect2, pindel, varscan2
- CYP2J2 | c.1080del p.Y361Tfs*18 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- GABRB3 | c.1104del p.L369* | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- IL12RB2 | c.1079_1080dup p.Q361Ifs*3 | Frame Shift Ins (INS) | VAF 131/395 reads (33%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.4172_4183del p.A1391_K1395delinsE | In Frame Del (DEL) | VAF 30/100 reads (30%) | called by pindel, varscan2
- PSG9 | c.1243+1del p.X415_splice | Splice Site (DEL) | VAF 43/117 reads (37%) | called by mutect2, pindel, varscan2
- SDHAF3 | c.272dup p.N91Kfs*2 | Frame Shift Ins (INS) | VAF 590/1036 reads (57%) | called by mutect2, pindel, varscan2
- TNRC18 | c.8046_8049del p.D2682Efs*118 | Frame Shift Del (DEL) | VAF 41/89 reads (46%) | called by mutect2, pindel, varscan2
- TULP4 | c.873_894del p.Q291Hfs*22 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- USP15 | c.1132_1138del p.Q378Tfs*6 (on ENST00000280377 / NM_001351159.2; = p.Q349Tfs*6 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/99 reads (42%) | called by mutect2, pindel, varscan2
- CCDC17 | c.558G>T p.L186= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV99322626; called by muse, mutect2, varscan2
- DSG4 | c.459C>T p.N153= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as rs749138368, COSV100356160; called by muse, mutect2, varscan2
- ECD | c.1248A>G p.L416= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100881484; called by muse, mutect2, varscan2
- FCRL4 | c.1377A>T p.G459= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV99620242; called by muse, mutect2, varscan2
- GRIN2C | c.2850C>T p.D950= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99501310; called by muse, mutect2, varscan2
- ISM1 | c.795A>G p.E265= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV99340204; called by muse, mutect2, varscan2
- KIFC1 | c.141G>A p.E47= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as rs368144446; called by muse, mutect2, varscan2
- MRPL46 | c.63G>A p.R21= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as rs540944922, COSV100363792; called by muse, mutect2, varscan2
- PLEKHH3 | c.1080C>A p.T360= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as rs1345806432, COSV52219673, COSV99257894; called by muse, mutect2, varscan2
- PPFIBP2 | c.1407T>C p.A469= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV100206824; called by muse, mutect2, varscan2
- PPL | c.4665C>G p.S1555= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99278452; called by muse, mutect2, varscan2
- PPP2R3C | c.276T>C p.D92= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99808845; called by muse, mutect2, varscan2
- RALGDS | c.2475T>G p.A825= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100924529; called by muse, mutect2, varscan2
- SACS | c.8847T>C p.I2949= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV101207609; called by muse, mutect2
- SLC6A2 | c.675C>T p.S225= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs753018279, COSV54915223; called by muse, mutect2, varscan2
- ZNF280D | c.2220A>G p.K740= | Silent (SNP) | VAF 157/399 reads (39%) | catalogued as rs1330609203, COSV99974941; called by muse, mutect2, varscan2
- SSPOP | n.13011C>T | RNA (SNP) | VAF 29/72 reads (40%) | catalogued as rs1428033407, COSV65134102; called by muse, mutect2, varscan2
- WWP2 | c.1683-789dup | Intron (INS) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
